Somatic mutation profile of tumor specimen MP2PRT-PAVFHX-TMP1-A (aliquot MP2PRT-PAVFHX-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVFHX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,620 days).
Specimen MP2PRT-PAVFHX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cae93287-14ce-416e-9452-04ca38003130.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFHX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFHX-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a5ed81f-4015-4dd8-9096-3eea24b57e11

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBY2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 180/469 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs761413589, COSV60117619; called by muse, mutect2, varscan2
- MAGEB6B | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as rs1248964358; called by muse, mutect2
- SIK3 | c.3134G>A p.R1045Q (on ENST00000445177 / NM_001366686.2; = p.R1003Q on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.006); catalogued as rs901812167, COSV52625969; called by muse, mutect2
- BTBD16 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- IGHV3-53 | c.349_350insGGAAAG | In Frame Ins (INS) | VAF 30/78 reads (38%) | called by pindel, varscan2
- PLEKHG6 | c.1771G>C p.G591R | Missense Mutation (SNP) | VAF 64/642 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- RNF213 | c.188_199del p.L63_G66del | In Frame Del (DEL) | VAF 77/301 reads (26%) | called by mutect2, pindel, varscan2
